Gene-level copy-number profile of tumor specimen TCGA-24-2280-01A from TCGA case TCGA-24-2280, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.9 years (27,356 days).
Specimen TCGA-24-2280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4d5e8e9e-46a0-4b04-ba87-edb5d1c79347.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2280-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae506cf7-05f3-4b3b-a49d-210ee21066ee

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,090; copy number 2: 13,036; copy number 3: 16,689; copy number 4: 16,561; copy number 5: 8,795; copy number 6: 3,079; copy number 7: 483; copy number 8: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2280-01A-01D-0704-01): tumor purity 0.59, ploidy 3.56, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 553 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:183,472,216–184,335,949, 15 genes, copy number 7 (within-gene range 5–7): SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P.
- chr1:204,828,651–205,684,307, 27 genes, copy number 8 (within-gene range 5–8): NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP.
- chr1:224,896,262–225,941,383, 19 genes, copy number 8 (within-gene range 2–8): DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2.
- chr3:117,672,154–117,997,592, 4 genes, copy number 7: AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr5:148,451,032–167,168,401, 270 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:167,287,320–167,309,870, 3 genes, copy number 7: AC091820.2, AC091820.1, AC008601.1.
- chr6:19,143,695–21,383,200, 28 genes, copy number 7: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2.
- chr6:30,557,280–30,848,159, 24 genes, copy number 8 (within-gene range 6–8): PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570.
- chr7:151,877,042–152,465,549, 17 genes, copy number 7: PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5, Metazoa_SRP, GALNT11, AC006017.1, YBX1P4, KMT2C, AC104692.2, AC104692.1, SEPTIN7P6, Y_RNA, FABP5P3, CCT8L1P, LINC01003.
- chr16:35,169,692–35,912,516, 68 genes, copy number 7 (broad region; genes not listed).
- chr20:34,872,146–36,746,090, 71 genes, copy number 7 (broad region; genes not listed).
- chr22:34,589,085–34,724,919, 4 genes, copy number 7: AL021877.1, AL021877.2, Z82196.1, Z82196.2.
- chr22:35,119,824–35,231,056, 1 gene, copy number 7 (within-gene range 3–7): LINC01399.
- chr22:35,164,304–35,249,833, 2 genes, copy number 7: Z99755.1, RNU7-167P.

Autosomal genes at a single copy (total copy number 1): 582. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
